MMRF case MMRF_1601 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/da7c1425-a8c7-4f9c-94a0-85ef517e9c2d

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 84 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 84.8 years (30,975 days); ISS stage: III; Days to last known disease status: 1 day; Days to last follow up: 1 day.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 16 days.

Follow-up (2 entries)
- Days to follow up: -2 days; ECOG performance status: 2.
- Follow-up contact recording only the day: day 1.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Beta 2 Microglobulin 8.5 µg/mL.
- Total Protein 7.7 g/dL.
- Albumin 34 g/L.
- Calcium 2.63 mmol/L.
- Serum Free Immunoglobulin Light Chain, Kappa 91.8 mg/dL.
- Serum Free Immunoglobulin Light Chain, Lambda 0.41 mg/dL.
- Hemoglobin 5.89 mmol/L.
- Blood Urea Nitrogen 19.6 mmol/L.
- Creatinine 194 µmol/L.
- Absolute Neutrophil 3.9 ×10⁹/L.
- Leukocytes 5.7 ×10⁹/L.
- Glucose 5.89 mmol/L.
- Platelets 329 ×10⁹/L.

Other clinical attributes
- Day -2: Weight: 48 kg; Height: 154 cm.

Biospecimens (2 samples)
- Sample MMRF_1601_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -2 days.
- Sample MMRF_1601_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -2 days.
